Somatic mutation profile of tumor specimen 0DECXF from CCDI case PBBKPM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.6 years (3,873 days).
Specimen 0DECXF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42a70b9c-c5b3-4f39-90a0-2407a346bc19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DECX2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0724723b-b15e-49ec-9469-8f5d8af6441c

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 1, Splice Site 1, 5'UTR 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIPR1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 324/1042 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs369948823; called by muse, varscan2
- SALL1 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 329/1154 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs778842406, COSV51757456; called by muse, varscan2
- SLC22A12 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 244/772 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.508); catalogued as rs771298905, COSV100327338, COSV60574985; called by muse, varscan2
- UGT1A9 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 272/1184 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100691752; called by muse, varscan2
- LANCL1 | c.1121A>T p.E374V | Missense Mutation (SNP) | VAF 144/518 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LANCL1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 146/526 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- PRDM9 | c.1144+1G>C p.X382_splice | Splice Site (SNP) | VAF 390/1286 reads (30%) | called by muse, varscan2
- SLC17A3 | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 359/1105 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, varscan2
- STPG2 | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 304/1024 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, varscan2
- UGT1A9 | c.447T>G p.P149= | Silent (SNP) | VAF 282/1200 reads (24%) | called by muse, varscan2
- CTNS | c.*437C>G | 3'UTR (SNP) | VAF 64/186 reads (34%) | called by muse, varscan2
- MPPE1 | c.867+15C>T | Intron (SNP) | VAF 69/232 reads (30%) | catalogued as rs762764662; called by muse, varscan2
- TOR1A | c.-20A>T | 5'UTR (SNP) | VAF 174/492 reads (35%) | catalogued as rs772405181; called by muse, varscan2
